FM case AD17201 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/0c6163fc-f3e5-4fc1-b6e2-f2b5d12c3786

Female, 62.6 years: Serous carcinoma, NOS (ICD-O-3 8441/3) of the ovary; metastasis biopsied or resected from the vagina. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
